Somatic mutation profile of tumor specimen MMRF_1960_1_BM_CD138pos (aliquot MMRF_1960_1_BM_CD138pos_T1_KBS5U_L06456) from MMRF case MMRF_1960, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 72.3 years (26,397 days).
Specimen MMRF_1960_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56f73a90-7072-4749-b99a-59f2144930ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1960_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1960_1_PB_Whole_C2_KBS5U_L06489; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80a9e7f7-04f3-46b1-bd76-53767625d3ff

The open-access MAF lists 100 somatic variants for this specimen: 35 protein-altering or splice-affecting, 13 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 32, Missense Mutation 30, Silent 13, Intron 9, 3'Flank 3, 5'UTR 3, 5'Flank 3, Nonsense Mutation 2, Frame Shift Ins 2, RNA 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC4 | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.269); catalogued as rs761006351; called by muse, mutect2, varscan2
- BECN1 | c.-2-3C>T | Splice Region (SNP) | VAF 4/91 reads (4%) | catalogued as rs1323112027; called by muse, mutect2
- CDC42BPG | c.3917G>A p.R1306H | Missense Mutation (SNP) | VAF 80/116 reads (69%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs759473734, COSV100711999; called by muse, mutect2, varscan2
- DHDH | c.532G>A p.G178S | Missense Mutation (SNP) | VAF 83/143 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs750319188; called by muse, mutect2, varscan2
- DSN1 | c.769A>G p.M257V | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs1237719130; called by muse, mutect2, varscan2
- DUSP2 | c.252G>C p.E84D | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV56619478; called by muse, varscan2
- GALT | c.487G>A p.A163T | Missense Mutation (SNP) | VAF 55/297 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV66592976; called by muse, mutect2, varscan2
- IGHV3-23 | c.236A>C p.Y79S | Missense Mutation (SNP) | VAF 106/428 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as rs374612146; called by muse, varscan2
- IGLV3-1 | c.208A>G p.S70G | Missense Mutation (SNP) | VAF 57/61 reads (93%) | SIFT deleterious (0.04); PolyPhen benign (0.07); catalogued as rs143830449; called by muse, mutect2, varscan2
- KCNB1 | c.881G>A p.R294H | Missense Mutation (SNP) | VAF 73/88 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779573636, COSV65566374; called by muse, mutect2, varscan2
- MUC6 | c.7031C>T p.T2344I | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs374212587; called by muse, mutect2, varscan2
- PCDHGC4 | c.1187C>T p.A396V | Missense Mutation (SNP) | VAF 70/290 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as COSV104383015; called by muse, mutect2, varscan2
- PPRC1 | c.4657C>T p.R1553C | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs1224055531; called by muse, mutect2, varscan2
- RNF157 | c.1663dup p.Q555Pfs*37 | Frame Shift Ins (INS) | VAF 33/75 reads (44%) | catalogued as rs1344382682; called by mutect2, pindel, varscan2
- ZFHX4 | c.1230dup p.L411Afs*3 | Frame Shift Ins (INS) | VAF 33/123 reads (27%) | catalogued as rs761578656; called by mutect2, varscan2
- ZNF292 | c.505A>G p.I169V | Missense Mutation (SNP) | VAF 70/153 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.376); catalogued as rs746738863, COSV60539163; called by muse, mutect2, varscan2
- ABO | c.778G>T p.G260C | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKNA | c.3169T>C p.C1057R | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOL1 | c.232A>T p.K78* | Nonsense Mutation (SNP) | VAF 51/161 reads (32%) | called by muse, mutect2, varscan2
- BBS9 | c.2101G>A p.G701R (on ENST00000242067 / NM_001348036.1; = p.G661R on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/311 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- CDHR1 | c.1502C>A p.T501K | Missense Mutation (SNP) | VAF 52/113 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- CR1 | c.4951C>T p.Q1651* | Nonsense Mutation (SNP) | VAF 51/140 reads (36%) | called by muse, mutect2, varscan2
- DUSP2 | c.275A>C p.D92A | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.877); called by muse, varscan2
- FAT3 | c.7768G>T p.V2590F | Missense Mutation (SNP) | VAF 37/142 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- FNDC3A | c.2879T>C p.V960A (on ENST00000492622 / NM_001079673.2; = p.V904A on NM_014923.5) | Missense Mutation (SNP) | VAF 76/222 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- IGLV4-3 | c.328C>T p.H110Y | Missense Mutation (SNP) | VAF 41/47 reads (87%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- INTS2 | c.2612C>T p.P871L | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- INTS2 | c.2611C>T p.P871S | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ITGAL | c.26T>C p.M9T | Missense Mutation (SNP) | VAF 42/93 reads (45%) | SIFT tolerated (0.81); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PRAMEF12 | c.152C>A p.T51N | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PRIM2 | c.464G>C p.S155T | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRUNE1 | c.539G>T p.C180F | Missense Mutation (SNP) | VAF 104/229 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SOGA3 | c.2548G>A p.G850R | Missense Mutation (SNP) | VAF 71/139 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZBTB7A | c.1214C>A p.T405K | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZNF469 | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.621); called by muse, mutect2, varscan2
- AC135068.1 | c.640C>T p.L214= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as rs1175496960; called by muse, mutect2, varscan2
- ASPM | c.8427A>G p.A2809= | Silent (SNP) | VAF 96/218 reads (44%) | called by muse, mutect2, varscan2
- BIN2 | c.27G>C p.A9= | Silent (SNP) | VAF 40/80 reads (50%) | called by muse, mutect2, varscan2
- IGLV2-14 | c.78T>C p.P26= | Silent (SNP) | VAF 33/75 reads (44%) | catalogued as rs1396253616; called by muse, mutect2, varscan2
- IGLV3-25 | c.60C>G p.S20= | Silent (SNP) | VAF 54/117 reads (46%) | called by muse, mutect2, varscan2
- KCNG2 | c.390G>A p.A130= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2
- KIAA1755 | c.2049C>T p.V683= | Silent (SNP) | VAF 79/272 reads (29%) | called by muse, mutect2, varscan2
- NPFFR1 | c.1131G>C p.R377= | Silent (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2, varscan2
- RIMS2 | c.2058T>C p.D686= (on ENST00000666250 / NM_001348490.2; = p.D494= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs770142547; called by muse, mutect2, varscan2
- SP1 | c.1698T>C p.G566= (on ENST00000327443 / NM_138473.3; = p.G559= on NM_003109.1) | Silent (SNP) | VAF 21/52 reads (40%) | catalogued as rs769320858; called by muse, mutect2, varscan2
- SVEP1 | c.10299A>G p.Q3433= | Silent (SNP) | VAF 67/280 reads (24%) | catalogued as rs906303914; called by muse, mutect2, varscan2
- TNFRSF11A | c.1761C>T p.R587= | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- ZAR1L | c.138G>A p.R46= | Silent (SNP) | VAF 16/62 reads (26%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.-45C>T | 5'UTR (SNP) | VAF 30/84 reads (36%) | called by muse, mutect2, varscan2
- AL359555.4 | n.294G>C | RNA (SNP) | VAF 172/301 reads (57%) | called by muse, mutect2, varscan2
- ALDOB | c.*778A>C | 3'UTR (SNP) | VAF 8/185 reads (4%) | called by muse, mutect2
- APOL4 | c.*1485C>A | 3'UTR (SNP) | VAF 61/138 reads (44%) | called by muse, mutect2, varscan2
- AQP2 | c.*251G>A | 3'UTR (SNP) | VAF 17/52 reads (33%) | called by muse, mutect2, varscan2
- ATP2C1 | c.*1001A>G | 3'UTR (SNP) | VAF 20/79 reads (25%) | catalogued as rs1211888653; called by muse, mutect2, varscan2
- ATP6V1A | c.*1878del | 3'UTR (DEL) | VAF 34/202 reads (17%) | called by pindel, varscan2
- ATP6V1A | c.*1882T>A | 3'UTR (SNP) | VAF 38/186 reads (20%) | called by muse, varscan2
- ATP6V1D | chr14:67359820 T>A | 5'Flank (SNP) | VAF 57/111 reads (51%) | called by muse, mutect2, varscan2
- C22orf23 | c.*431T>C | 3'UTR (SNP) | VAF 41/87 reads (47%) | called by muse, mutect2, varscan2
- CD6 | c.1583-18C>A | Intron (SNP) | VAF 60/236 reads (25%) | called by muse, mutect2, varscan2
- CORO6 | c.754-158_754-136del | Intron (DEL) | VAF 54/179 reads (30%) | called by mutect2, varscan2
- CSMD3 | c.178+59764A>G | Intron (SNP) | VAF 26/61 reads (43%) | called by muse, mutect2, varscan2
- CYBC1 | c.*453G>A | 3'UTR (SNP) | VAF 4/27 reads (15%) | called by muse, mutect2
- DLG4 | chr17:7219548 C>T | 5'Flank (SNP) | VAF 90/218 reads (41%) | called by muse, mutect2, varscan2
- DNER | c.1610-53T>C | Intron (SNP) | VAF 11/22 reads (50%) | catalogued as rs1313649131; called by muse, mutect2, varscan2
- DR1 | chr1:93361836 A>G | 3'Flank (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- EPG5 | c.*618A>G | 3'UTR (SNP) | VAF 53/140 reads (38%) | catalogued as rs1366376467; called by muse, mutect2, varscan2
- FAH | chr15:80186787 A>T | 3'Flank (SNP) | VAF 15/81 reads (19%) | called by muse, mutect2, varscan2
- FAT3 | c.*1296G>T | 3'UTR (SNP) | VAF 6/22 reads (27%) | called by mutect2, varscan2
- FSTL4 | c.*199G>A | 3'UTR (SNP) | VAF 43/156 reads (28%) | catalogued as COSV99533195; called by muse, mutect2, varscan2
- GARNL3 | chr9:127263944 G>T | 5'Flank (SNP) | VAF 52/297 reads (18%) | called by muse, mutect2, varscan2
- HERC5 | c.-100C>T | 5'UTR (SNP) | VAF 22/41 reads (54%) | catalogued as rs564612502; called by muse, mutect2, varscan2
- KLHL6 | c.*1470T>A | 3'UTR (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- LANCL1 | chr2:210432068 G>C | 3'Flank (SNP) | VAF 39/107 reads (36%) | called by muse, mutect2, varscan2
- MBL2 | c.*279G>A | 3'UTR (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- NANOGP1 | n.1553C>T | RNA (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
- NAV2 | c.268-54657del | Intron (DEL) | VAF 18/58 reads (31%) | called by mutect2, pindel
- NCAM2 | c.*295G>C | 3'UTR (SNP) | VAF 44/139 reads (32%) | called by muse, mutect2, varscan2
- NSUN3 | c.*255G>A | 3'UTR (SNP) | VAF 27/89 reads (30%) | called by muse, mutect2, varscan2
- OAT | c.772-10del | Intron (DEL) | VAF 68/152 reads (45%) | catalogued as rs778743727; called by mutect2, varscan2
- PAWR | c.*4021A>C | 3'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
- PHF21A | c.*173C>T | 3'UTR (SNP) | VAF 16/43 reads (37%) | called by muse, mutect2
- PI4KB | c.*154G>T | 3'UTR (SNP) | VAF 51/104 reads (49%) | called by muse, mutect2, varscan2
- PMEPA1 | c.*900C>G | 3'UTR (SNP) | VAF 40/74 reads (54%) | called by muse, varscan2
- PMEPA1 | c.*833C>T | 3'UTR (SNP) | VAF 99/131 reads (76%) | catalogued as rs1482733327; called by muse, varscan2
- PMEPA1 | c.*744C>G | 3'UTR (SNP) | VAF 128/192 reads (67%) | called by muse, varscan2
- PPP3CB | c.*611C>A | 3'UTR (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- PYCR1 | c.*359G>A | 3'UTR (SNP) | VAF 25/50 reads (50%) | called by muse, mutect2, varscan2
- SF3A1 | c.*91C>T | 3'UTR (SNP) | VAF 4/44 reads (9%) | called by muse, mutect2
- SGSM3 | c.*446C>G | 3'UTR (SNP) | VAF 13/39 reads (33%) | called by muse, mutect2, varscan2
- SPCS2 | c.114+204C>A | Intron (SNP) | VAF 95/288 reads (33%) | called by muse, mutect2, varscan2
- ST7 | c.865+986A>G | Intron (SNP) | VAF 5/128 reads (4%) | called by muse, mutect2
- SYS1 | c.-3-13C>A | Intron (SNP) | VAF 22/24 reads (92%) | called by muse, mutect2, varscan2
- TRIM45 | c.-405G>A | 5'UTR (SNP) | VAF 21/45 reads (47%) | called by muse, mutect2, varscan2
- UBTF | c.*17A>G | 3'UTR (SNP) | VAF 36/71 reads (51%) | called by muse, mutect2, varscan2
- VAPA | c.*2555G>A | 3'UTR (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- VPS13A | c.*5331G>A | 3'UTR (SNP) | VAF 25/109 reads (23%) | called by muse, mutect2, varscan2
- VWA1 | c.*2077C>G | 3'UTR (SNP) | VAF 38/93 reads (41%) | called by muse, mutect2, varscan2
- YOD1 | c.*2115T>A | 3'UTR (SNP) | VAF 43/82 reads (52%) | called by muse, mutect2, varscan2
- ZNF202 | c.*1288C>G | 3'UTR (SNP) | VAF 57/197 reads (29%) | called by muse, mutect2, varscan2
- ZNF621 | c.*2084G>C | 3'UTR (SNP) | VAF 41/198 reads (21%) | called by muse, mutect2, varscan2
